Somatic mutation profile of tumor specimen ALCH-B0EY-TTP1-A (aliquot ALCH-B0EY-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0EY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.5 years (29,049 days).
Specimen ALCH-B0EY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efdfbb8f-de97-4a19-9169-807dd0e3bac2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0EY-NB1-A (Blood Derived Normal), aliquot ALCH-B0EY-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3fcffc1-7d34-49ae-b176-7093c802a234

The open-access MAF lists 401 somatic variants for this specimen: 285 protein-altering or splice-affecting, 80 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 250, Silent 80, Nonsense Mutation 18, Intron 16, RNA 8, Frame Shift Del 8, Splice Site 6, 3'UTR 5, 5'UTR 4, Splice Region 2, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2E | c.3070C>T p.Q1024* | Nonsense Mutation (SNP) | VAF 35/194 reads (18%) | catalogued as rs1562931936; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.7355G>A p.R2452Q | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs193922815, CM064218, CM091639; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 120/736 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSM5 | c.767G>T p.R256I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100088610; called by muse, mutect2, varscan2
- AKAP6 | c.2503C>G p.L835V | Missense Mutation (SNP) | VAF 71/297 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754215086; called by muse, varscan2
- AKR1B1 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 54/808 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.071); catalogued as rs1484242051; called by muse, mutect2
- AP000812.4 | c.446T>C p.I149T | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as rs976844118; called by muse, mutect2, varscan2
- ARPP21 | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV51799248; called by muse, mutect2, varscan2
- ASF1A | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 23/333 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs925727394; called by muse, mutect2
- BICRA | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV67604338; called by muse, mutect2, varscan2
- BRCC3 | c.124-2A>G p.X42_splice | Splice Site (SNP) | VAF 39/182 reads (21%) | catalogued as COSV57461979; called by muse, mutect2, varscan2
- CD163 | c.2596C>T p.Q866* | Nonsense Mutation (SNP) | VAF 68/572 reads (12%) | catalogued as COSV63136015; called by muse, varscan2
- CDH10 | c.2105C>A p.P702H | Missense Mutation (SNP) | VAF 65/452 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV100051741; called by muse, mutect2, varscan2
- CDH8 | c.1292G>T p.R431L | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as COSV54867299; called by muse, mutect2, varscan2
- CECR2 | c.2682G>T p.Q894H (on ENST00000342247 / NM_001290047.2; = p.Q711H on NM_001290046.1) | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV52848459, COSV99377596; called by muse, mutect2
- CHRD | c.2000G>T p.R667L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.039); catalogued as rs754915047; called by mutect2, varscan2
- CLMN | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 41/487 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs867784846, COSV100112960; called by muse, mutect2
- CNGB3 | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100181771; called by muse, mutect2, varscan2
- CSMD1 | c.9575C>G p.S3192C (on ENST00000520002; = p.S3191C on NM_033225.6) | Missense Mutation (SNP) | VAF 70/299 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59304948; called by muse, mutect2, varscan2
- CSNK2A3 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 91/668 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs755106332; called by muse, mutect2, varscan2
- DDX54 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 13/123 reads (11%) | catalogued as COSV58375539; called by muse, mutect2, varscan2
- DGKI | c.1419G>A p.W473* | Nonsense Mutation (SNP) | VAF 18/87 reads (21%) | catalogued as COSV99068397; called by muse, mutect2, varscan2
- DNAH1 | c.6493G>A p.D2165N | Missense Mutation (SNP) | VAF 31/416 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as rs761325487; called by muse, mutect2
- EPHA6 | c.1564C>A p.P522T | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV101060623, COSV67562008; called by muse, mutect2, varscan2
- FAM47A | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60495592; called by muse, mutect2, varscan2
- FBLN1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.99); catalogued as rs1258806822; called by muse, mutect2
- FBXL18 | c.13G>C p.G5R | Missense Mutation (SNP) | VAF 159/357 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.352); catalogued as COSV101212024; called by muse, mutect2, varscan2
- GALNT6 | c.1533T>A p.D511E | Missense Mutation (SNP) | VAF 30/269 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216344505; called by muse, mutect2, varscan2
- GCSAML | c.357G>T p.R119S | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV100825969; called by muse, mutect2, varscan2
- GORASP2 | c.1180C>A p.P394T | Missense Mutation (SNP) | VAF 31/347 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.057); catalogued as COSV52201331; called by muse, mutect2
- GPATCH1 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 30/416 reads (7%) | catalogued as rs35914956; called by muse, mutect2
- GSAP | c.1625A>G p.Y542C | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs756419307, COSV99990518; called by muse, mutect2, varscan2
- HS3ST4 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 55/966 reads (6%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.805); catalogued as rs1333774695; called by muse, mutect2
- HSD3B1 | c.972T>A p.N324K | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs750650029; called by muse, mutect2, varscan2
- IFNG | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV57491354; called by muse, mutect2, varscan2
- IFT122 | c.2560G>T p.G854C (on ENST00000348417 / NM_052989.3; = p.G795C on NM_018262.4) | Missense Mutation (SNP) | VAF 46/813 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV56200967; called by muse, mutect2
- ITGA8 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1373952589; called by muse, mutect2, varscan2
- KDR | c.2974C>T p.P992S | Missense Mutation (SNP) | VAF 18/508 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1483707001, COSV55757192, COSV55767520; called by muse, mutect2
- KLHL33 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 46/428 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs573523834, COSV60727128; called by muse, mutect2, varscan2
- KLHL36 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.553); catalogued as rs762545271, COSV50718231; called by muse, mutect2, varscan2
- LAMA2 | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 18/337 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as rs760219197; called by muse, mutect2
- LEKR1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.297); catalogued as rs1156653386; called by muse, mutect2, varscan2
- LIPI | c.704A>G p.N235S | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs758215638, COSV60712653; called by muse, mutect2
- LRFN5 | c.2065G>T p.G689W | Missense Mutation (SNP) | VAF 101/397 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV53265345; called by muse, mutect2, varscan2
- MAP1A | c.6644A>G p.D2215G | Missense Mutation (SNP) | VAF 51/372 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as rs780549707; called by muse, mutect2, varscan2
- MYF6 | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 61/609 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV57354080; called by muse, mutect2, varscan2
- MYT1L | c.14C>G p.T5S | Missense Mutation (SNP) | VAF 60/558 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV67710802; called by muse, mutect2, varscan2
- NAV1 | c.3371G>A p.R1124H | Missense Mutation (SNP) | VAF 30/435 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1208037567, COSV55219335; called by muse, mutect2
- NAV3 | c.2356C>T p.R786C | Missense Mutation (SNP) | VAF 37/361 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs774139179; called by muse, mutect2, varscan2
- NEB | c.14371A>G p.I4791V | Missense Mutation (SNP) | VAF 32/454 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.098); catalogued as rs746334983; called by muse, mutect2
- NEBL | c.2950G>A p.V984M | Missense Mutation (SNP) | VAF 59/306 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1233847176; called by muse, mutect2, varscan2
- NOP2 | c.2323G>A p.D775N (on ENST00000322166 / NM_001258308.2; = p.D771N on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/702 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs959288805; called by muse, mutect2
- NTN4 | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1267383332; called by muse, mutect2, varscan2
- OR14C36 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV58603053; called by muse, mutect2, varscan2
- OR1D5 | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 58/686 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs908457948; called by muse, mutect2
- OR4C13 | c.661T>C p.Y221H | Missense Mutation (SNP) | VAF 25/406 reads (6%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as COSV73648811; called by muse, mutect2
- OR4S2 | c.725T>A p.I242N | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56746472; called by muse, mutect2, varscan2
- OR51L1 | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); catalogued as rs1338188149; called by muse, mutect2, varscan2
- OR5AC2 | c.119C>A p.T40N | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1469840869; called by muse, mutect2
- OR7C2 | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 62/438 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.925); catalogued as COSV99027958; called by muse, varscan2
- PCDHB6 | c.523C>A p.P175T | Missense Mutation (SNP) | VAF 41/224 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.398); catalogued as COSV99039404; called by muse, mutect2, varscan2
- PCDHB9 | c.1873C>A p.R625S | Missense Mutation (SNP) | VAF 35/358 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as rs1429547431; called by mutect2, varscan2
- PCDHGA7 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 38/727 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV53994051; called by muse, mutect2
- PCLO | c.10775G>A p.R3592H | Missense Mutation (SNP) | VAF 64/351 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs778838697, COSV61621173; called by muse, mutect2, varscan2
- PDZRN4 | c.1366-1G>T p.X456_splice (on ENST00000402685 / NM_001164595.2; = p.X198_splice on NM_013377.4) | Splice Site (SNP) | VAF 23/214 reads (11%) | catalogued as rs1394672079; called by muse, mutect2, varscan2
- PHF24 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs781343380, COSV54275816; called by muse, mutect2
- PLA2G2F | c.617C>G p.A206G | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs778561670, COSV64279877; called by muse, mutect2, varscan2
- PLAU | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 41/443 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.103); catalogued as rs986636149, COSV65641757; called by muse, mutect2
- PPRC1 | c.3091C>A p.P1031T | Missense Mutation (SNP) | VAF 57/394 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV53383576; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1378G>T p.G460W (on ENST00000352766; = p.G381W on NM_181334.5) | Missense Mutation (SNP) | VAF 50/267 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs754945300; called by muse, mutect2, varscan2
- PRUNE2 | c.3922G>T p.G1308W | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV65043144; called by muse, mutect2, varscan2
- PSG11 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs771500183; called by muse, mutect2, varscan2
- PTDSS1 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 58/532 reads (11%) | catalogued as COSV61263638; called by muse, varscan2
- RAD18 | c.1139C>A p.S380Y | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV99368903; called by muse, mutect2, varscan2
- RPH3A | c.1744G>C p.A582P (on ENST00000389385 / NM_001143854.2; = p.A578P on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV101231806; called by muse, mutect2
- RSF1 | c.3121G>A p.A1041T | Missense Mutation (SNP) | VAF 59/417 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs774617164; called by muse, mutect2, varscan2
- SETD1A | c.2028G>A p.M676I | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.201); catalogued as rs372998566; called by muse, mutect2, varscan2
- SLC7A14 | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 32/521 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.235); catalogued as rs375762552; called by muse, mutect2
- SNAP25 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 47/292 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.81); catalogued as COSV54770803; called by muse, mutect2, varscan2
- SULT6B1 | c.198C>T p.C66= (on ENST00000535679 / NM_001367551.1; = p.C28= on NM_001032377.2) | Splice Region (SNP) | VAF 17/118 reads (14%) | catalogued as rs769158962, COSV53193845, COSV99573170; called by muse, mutect2, varscan2
- TAF4 | c.3070G>T p.G1024W | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV53339521; called by muse, mutect2, varscan2
- TBX3 | c.911G>C p.R304P (on ENST00000257566 / NM_016569.4; = p.R284P on NM_005996.4) | Missense Mutation (SNP) | VAF 64/444 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57469903; called by muse, mutect2, varscan2
- TG | c.3640C>T p.R1214W | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs751074855, COSV55065706; called by muse, mutect2, varscan2
- TGM1 | c.38del p.G13Vfs*98 | Frame Shift Del (DEL) | VAF 27/236 reads (11%) | catalogued as CX135313; called by mutect2, pindel, varscan2
- TMEM132B | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 67/443 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV54745304; called by muse, mutect2, varscan2
- TMEM132C | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 28/242 reads (12%) | catalogued as COSV59433280; called by muse, mutect2, varscan2
- TRIM9 | c.568T>C p.C190R | Missense Mutation (SNP) | VAF 90/502 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100031124; called by muse, mutect2, varscan2
- TRIP12 | c.1991G>C p.S664T | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV52273076; called by muse, mutect2
- TRRAP | c.7342C>T p.R2448C (on ENST00000359863 / NM_001244580.1; = p.R2430C on NM_003496.3) | Missense Mutation (SNP) | VAF 128/606 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs1390223813, COSV62847845; called by muse, mutect2, varscan2
- TSHZ2 | c.2008C>A p.L670M | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV61587605; called by muse, mutect2
- TSPAN12 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 53/326 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV56082213; called by muse, mutect2, varscan2
- TXLNA | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 30/526 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.075); catalogued as rs1170296159, COSV65314192; called by muse, mutect2
- UCMA | c.32G>A p.C11Y | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.568); catalogued as COSV66321637; called by muse, mutect2, varscan2
- USP18 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 49/394 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99306078; called by muse, mutect2, varscan2
- VEGFC | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 39/342 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.261); catalogued as COSV54596369; called by muse, mutect2, varscan2
- VN1R4 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.06); catalogued as COSV60804578; called by muse, mutect2
- WDFY4 | c.2139G>T p.E713D | Missense Mutation (SNP) | VAF 38/537 reads (7%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.514); catalogued as rs759195843; called by muse, mutect2
- ZIC1 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV51558258; called by muse, mutect2
- ZNF415 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV54704042; called by muse, mutect2
- ZNF521 | c.3835C>A p.H1279N | Missense Mutation (SNP) | VAF 272/517 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64133038; called by muse, mutect2, varscan2
- ZP4 | c.452G>T p.R151I | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63913237; called by muse, mutect2, varscan2
- ACACB | c.2488dup p.R830Pfs*19 | Frame Shift Ins (INS) | VAF 11/87 reads (13%) | called by mutect2, pindel
- ADAM2 | c.436A>G p.K146E | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2
- ADAMTS16 | c.1608C>T p.D536= | Splice Region (SNP) | VAF 21/173 reads (12%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.2909A>T p.Y970F | Missense Mutation (SNP) | VAF 24/399 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.596); called by muse, mutect2
- ADCY10 | c.2066A>C p.N689T | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); called by muse, mutect2
- ADCY2 | c.1482G>T p.M494I | Missense Mutation (SNP) | VAF 54/317 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ADCY8 | c.998C>A p.T333K | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ADGB | c.4180T>A p.W1394R | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADGB | c.4345C>A p.P1449T | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2
- ADGRF2 | c.1267T>C p.C423R (on ENST00000296862 / NM_001368115.2; = p.C355R on NM_153839.7) | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALDH3B2 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALKBH5 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 68/335 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- ALYREF | c.502A>G p.K168E | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.101); called by muse, mutect2
- ANHX | c.1010C>A p.P337H | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2
- ANKFN1 | c.1450-2A>G p.X484_splice | Splice Site (SNP) | VAF 24/118 reads (20%) | called by muse, mutect2, varscan2
- ANKS1B | c.1057T>A p.S353T | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ANO5 | c.2578G>A p.D860N | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- ATP7B | c.4130A>C p.K1377T | Missense Mutation (SNP) | VAF 39/648 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2
- BPIFB3 | c.1003C>A p.Q335K | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C15orf39 | c.2338G>T p.G780C | Missense Mutation (SNP) | VAF 54/385 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- C15orf39 | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 55/383 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- C1orf87 | c.392A>T p.Q131L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- C20orf144 | c.62C>G p.P21R | Missense Mutation (SNP) | VAF 87/385 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C20orf85 | c.333C>A p.C111* | Nonsense Mutation (SNP) | VAF 70/342 reads (20%) | called by muse, mutect2, varscan2
- CA2 | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 54/684 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- CALB2 | c.627G>T p.K209N | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CALB2 | c.627+1G>T p.X209_splice | Splice Site (SNP) | VAF 23/166 reads (14%) | called by muse, mutect2, varscan2
- CAMKMT | c.718A>T p.R240* | Nonsense Mutation (SNP) | VAF 27/230 reads (12%) | called by mutect2, varscan2
- CAMKV | c.286T>C p.F96L | Missense Mutation (SNP) | VAF 14/430 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by muse, mutect2
- CCDC197 | c.582C>G p.S194R | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CD2AP | c.1373C>A p.S458* | Nonsense Mutation (SNP) | VAF 24/424 reads (6%) | called by muse, mutect2
- CD33 | c.513G>T p.Q171H | Missense Mutation (SNP) | VAF 44/399 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- CDC5L | c.160_161del p.L54Gfs*5 | Frame Shift Del (DEL) | VAF 31/163 reads (19%) | called by mutect2, pindel, varscan2
- CDH10 | c.2104C>A p.P702T | Missense Mutation (SNP) | VAF 65/456 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CELF3 | c.976C>A p.Q326K | Missense Mutation (SNP) | VAF 123/389 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CHD7 | c.6028A>T p.S2010C | Missense Mutation (SNP) | VAF 52/982 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CHL1 | c.1241C>A p.A414D (on ENST00000397491 / NM_001253387.1; = p.A430D on NM_006614.4) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLASP2 | c.278T>C p.I93T | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- CLCA2 | c.731A>T p.Q244L | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- CNTN5 | c.2890G>T p.E964* | Nonsense Mutation (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- COL17A1 | c.2560A>C p.N854H | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- COL21A1 | c.2812C>A p.P938T | Missense Mutation (SNP) | VAF 30/532 reads (6%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL21A1 | c.1705-1G>T p.X569_splice | Splice Site (SNP) | VAF 62/289 reads (21%) | called by muse, mutect2, varscan2
- COL5A2 | c.2167G>C p.G723R | Missense Mutation (SNP) | VAF 28/490 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CRLF2 | c.610T>A p.S204T | Missense Mutation (SNP) | VAF 32/540 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.163); called by muse, mutect2
- CROCC | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 32/476 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2
- CSMD3 | c.8689del p.V2897* (on ENST00000297405 / NM_001363185.1; = p.V2728* on NM_052900.3) | Frame Shift Del (DEL) | VAF 69/572 reads (12%) | called by mutect2, pindel, varscan2
- CYP3A4 | c.280C>G p.L94V | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- CYSLTR2 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.384); called by muse, mutect2
- DGKB | c.881G>T p.C294F | Missense Mutation (SNP) | VAF 26/472 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DGKI | c.962C>A p.P321H | Missense Mutation (SNP) | VAF 35/213 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMRT1 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- DMTF1 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 49/309 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- DNAJC6 | c.2516C>G p.T839R | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSEL | c.2895G>T p.K965N | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYNC2H1 | c.9373G>T p.D3125Y | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); called by muse, mutect2
- EGF | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 32/478 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.422); called by muse, mutect2
- EGR2 | c.1276C>G p.R426G | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- EPHX4 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- ESYT2 | c.2102C>T p.T701I (on ENST00000613624; = p.T625I on NM_020728.3) | Missense Mutation (SNP) | VAF 79/467 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- FAM171B | c.2397G>T p.R799S | Missense Mutation (SNP) | VAF 33/251 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- FAT2 | c.7072C>T p.P2358S | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FBN2 | c.1083G>C p.Q361H | Missense Mutation (SNP) | VAF 104/670 reads (16%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FBXO4 | c.991A>G p.I331V | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FGA | c.2352G>T p.Q784H | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2
- FMNL3 | c.2828G>T p.R943L | Missense Mutation (SNP) | VAF 91/665 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GALNT10 | c.11_14del p.K4Rfs*67 | Frame Shift Del (DEL) | VAF 3/37 reads (8%) | called by mutect2, pindel
- GAN | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 73/587 reads (12%) | called by muse, mutect2, varscan2
- GAS2L2 | c.927G>C p.M309I | Missense Mutation (SNP) | VAF 21/468 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2
- GPATCH1 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 14/305 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- GRID2IP | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2
- GRK4 | c.1645C>A p.P549T | Missense Mutation (SNP) | VAF 26/482 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, mutect2
- GTF3C1 | c.4532_4545del p.F1511Sfs*25 | Frame Shift Del (DEL) | VAF 29/178 reads (16%) | called by mutect2, pindel
- HCN4 | c.1231C>G p.L411V | Missense Mutation (SNP) | VAF 23/568 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- HDLBP | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 51/415 reads (12%) | called by muse, mutect2, varscan2
- HEPH | c.605C>A p.P202H (on ENST00000343002; = p.P256H on NM_138737.5) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HTR2A | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IFIT1B | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.58); called by muse, mutect2
- IGKV1-16 | c.22C>A p.Q8K | Missense Mutation (SNP) | VAF 48/465 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.43); called by muse, mutect2
- INHA | c.968G>T p.G323V | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- INSYN2B | c.1009C>A p.Q337K | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- JAKMIP1 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.142); called by mutect2, varscan2
- JAKMIP3 | c.2199G>T p.L733F | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- JCAD | c.3501G>T p.R1167S | Missense Mutation (SNP) | VAF 36/315 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- KCND3 | c.863C>A p.T288K | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KCNG4 | c.1099T>A p.C367S | Missense Mutation (SNP) | VAF 73/533 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- KIAA1109 | c.14234A>C p.H4745P | Missense Mutation (SNP) | VAF 35/446 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- KLHDC7A | c.959G>T p.R320M | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); called by mutect2, varscan2
- LMO7 | c.2621C>G p.S874* (on ENST00000357063; = p.S555* on NM_005358.5) | Nonsense Mutation (SNP) | VAF 30/589 reads (5%) | called by muse, mutect2
- LPA | c.3545C>A p.T1182N | Missense Mutation (SNP) | VAF 16/306 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRRC7 | c.1175C>G p.S392C (on ENST00000651989 / NM_001370785.2; = p.S359C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); called by muse, mutect2
- LRRC7 | c.3941G>T p.R1314I (on ENST00000651989 / NM_001370785.2; = p.R1281I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LTBP3 | c.2093C>G p.P698R | Missense Mutation (SNP) | VAF 40/473 reads (8%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.462); called by muse, mutect2
- MC5R | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MMP11 | c.152G>T p.W51L | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMS22L | c.3395T>C p.L1132P | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2
- MRPL21 | c.270del p.Q91Sfs*18 | Frame Shift Del (DEL) | VAF 32/295 reads (11%) | called by mutect2, pindel, varscan2
- MUL1 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 27/445 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- MYOF | c.4904G>T p.G1635V | Missense Mutation (SNP) | VAF 22/583 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- NEB | c.3900G>T p.W1300C | Missense Mutation (SNP) | VAF 57/460 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEXMIF | c.1897G>C p.G633R | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- NIPBL | c.2136G>C p.E712D | Missense Mutation (SNP) | VAF 25/394 reads (6%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.142); called by muse, mutect2
- NLRC3 | c.1320G>C p.Q440H | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.518); called by muse, mutect2
- NPAS2 | c.1605C>G p.C535W | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- NPY5R | c.1161C>A p.F387L | Missense Mutation (SNP) | VAF 30/371 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NR0B1 | c.540G>T p.R180S | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OPA1 | c.2053A>T p.T685S (on ENST00000361510 / NM_130837.3; = p.T630S on NM_015560.3) | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.014); called by muse, mutect2
- OPN4 | c.28C>G p.P10A | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR2AT4 | c.392T>A p.I131N | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2L5 | c.326C>A p.A109E | Missense Mutation (SNP) | VAF 86/379 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- OR5A2 | c.366C>A p.D122E | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OR5T1 | c.515C>G p.T172R | Missense Mutation (SNP) | VAF 38/281 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- OR6C6 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- OR7C1 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- OR8B8 | c.632C>G p.T211R | Missense Mutation (SNP) | VAF 59/496 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- OVCH1 | c.1329C>G p.N443K | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.169); called by muse, mutect2
- PARVG | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.127); called by muse, mutect2
- PCDH19 | c.1043T>C p.L348P | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA3 | c.1853C>G p.A618G | Missense Mutation (SNP) | VAF 86/416 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PCMTD1 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 54/383 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PDE6C | c.2036+2T>C p.X679_splice | Splice Site (SNP) | VAF 24/422 reads (6%) | called by muse, mutect2
- PDHB | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 20/226 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PDLIM5 | c.1357A>G p.M453V | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- PDS5A | c.452A>G p.Y151C | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PEG3 | c.1028G>T p.R343I | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- PGK2 | c.96C>A p.N32K | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- PHC1 | c.1948G>C p.D650H | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2
- PHF14 | c.2824G>T p.E942* | Nonsense Mutation (SNP) | VAF 47/181 reads (26%) | called by muse, mutect2, varscan2
- PIK3CG | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PKHD1 | c.1555G>C p.D519H | Missense Mutation (SNP) | VAF 124/558 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PKHD1L1 | c.3164G>A p.G1055D | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PLCXD3 | c.315C>A p.D105E | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PLEKHG2 | c.1622C>T p.S541L | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLEKHH1 | c.1796G>T p.W599L | Missense Mutation (SNP) | VAF 23/500 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- POT1 | c.1766del p.M589Sfs*7 | Frame Shift Del (DEL) | VAF 25/156 reads (16%) | called by mutect2, pindel, varscan2
- PRAMEF10 | c.423G>T p.M141I | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2
- PRPS1L1 | c.424G>C p.V142L | Missense Mutation (SNP) | VAF 40/706 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2
- PRRC2C | c.2981G>T p.R994L (on ENST00000367742; = p.R992L on NM_015172.4) | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- RETSAT | c.452C>G p.S151C | Missense Mutation (SNP) | VAF 44/791 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2
- REXO2 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- RFPL4AL1 | c.264C>A p.N88K | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RYR2 | c.4702G>T p.A1568S | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.111); called by muse, varscan2
- SACS | c.9661G>C p.V3221L | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); called by muse, mutect2
- SCN7A | c.2164T>C p.Y722H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- SH3BP5L | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SHANK2 | c.460_461del p.Q154Vfs*106 | Frame Shift Del (DEL) | VAF 54/434 reads (12%) | called by pindel, varscan2
- SLC47A1 | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 61/297 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLC4A10 | c.604T>A p.S202T | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.127); called by muse, varscan2
- SMARCAD1 | c.2940A>T p.Q980H | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2
- SMIM10 | c.143G>T p.R48L | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SP140 | c.1958G>T p.W653L | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SP140 | c.1959G>T p.W653C | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SPATS2 | c.347A>C p.Q116P | Missense Mutation (SNP) | VAF 65/423 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTBN4 | c.4900G>T p.E1634* | Nonsense Mutation (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- ST8SIA1 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 51/285 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAF1C | c.1799G>T p.R600L | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- TBPL2 | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 139/563 reads (25%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TBX19 | c.1129A>T p.T377S | Missense Mutation (SNP) | VAF 113/543 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- TDRD6 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- TDRD7 | c.2333A>G p.Q778R | Missense Mutation (SNP) | VAF 87/587 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- TESMIN | c.170C>A p.A57E | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- TIFAB | c.470C>A p.P157H | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- TRBV23-1 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 45/326 reads (14%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- TRPC6 | c.2723A>T p.D908V | Missense Mutation (SNP) | VAF 50/430 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by mutect2, varscan2
- TTLL13P | c.1201T>C p.C401R | Missense Mutation (SNP) | VAF 61/367 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBA3D | c.801C>A p.F267L | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- UBE4A | c.1720G>A p.A574T (on ENST00000252108 / NM_001204077.2; = p.A581T on NM_004788.4) | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.42); called by muse, mutect2
- UGT2B10 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- VPS37D | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- VWF | c.7498G>C p.E2500Q | Missense Mutation (SNP) | VAF 34/924 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.554); called by muse, mutect2
- VWF | c.2513C>A p.P838H | Missense Mutation (SNP) | VAF 229/993 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- WBP11 | c.1318C>G p.P440A | Missense Mutation (SNP) | VAF 19/596 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- XIRP2 | c.8254T>A p.F2752I (on ENST00000628543; = p.F2927I on NM_152381.6) | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZIC1 | c.1126T>C p.S376P | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF135 | c.451C>A p.P151T (on ENST00000313434 / NM_001289401.2; = p.P163T on NM_003436.4) | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF251 | c.914G>C p.S305T | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF260 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 24/394 reads (6%) | called by muse, mutect2
- ZNF362 | c.1120A>T p.S374C | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF536 | c.1465C>A p.L489M | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ZNF585A | c.1826G>T p.S609I (on ENST00000292841 / NM_001288800.2; = p.S554I on NM_152655.3) | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF681 | c.1348T>A p.Y450N | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF729 | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2
- ZNF736 | c.1196G>T p.C399F | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF835 | c.269C>A p.P90Q | Missense Mutation (SNP) | VAF 70/526 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.613); called by muse, varscan2
- ABCA12 | c.2079C>A p.S693= (on ENST00000272895 / NM_173076.3; = p.S375= on NM_015657.3) | Silent (SNP) | VAF 44/319 reads (14%) | called by muse, mutect2, varscan2
- ABCA4 | c.312G>A p.R104= | Silent (SNP) | VAF 129/1010 reads (13%) | called by muse, mutect2, varscan2
- ACTN3 | c.2020C>T p.L674= | Silent (SNP) | VAF 34/213 reads (16%) | called by muse, mutect2, varscan2
- ADAM2 | c.636G>T p.T212= | Silent (SNP) | VAF 26/239 reads (11%) | catalogued as COSV55867570; called by muse, mutect2, varscan2
- ADAMTS4 | c.858C>A p.A286= | Silent (SNP) | VAF 66/252 reads (26%) | called by muse, mutect2, varscan2
- APBA2 | c.2088G>T p.V696= | Silent (SNP) | VAF 73/402 reads (18%) | called by muse, mutect2, varscan2
- ARID4B | c.2961A>T p.P987= | Silent (SNP) | VAF 112/393 reads (28%) | called by muse, mutect2, varscan2
- ATP6V0D1 | c.363C>T p.S121= | Silent (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- BORCS6 | c.789T>C p.D263= | Silent (SNP) | VAF 29/164 reads (18%) | called by muse, mutect2, varscan2
- C16orf96 | c.1584C>G p.V528= | Silent (SNP) | VAF 86/568 reads (15%) | called by muse, varscan2
- C1QL2 | c.195C>T p.L65= | Silent (SNP) | VAF 12/124 reads (10%) | called by muse, mutect2
- CEP170 | c.2055G>A p.Q685= | Silent (SNP) | VAF 122/552 reads (22%) | called by muse, varscan2
- CHL1 | c.1242C>A p.A414= (on ENST00000397491 / NM_001253387.1; = p.A430= on NM_006614.4) | Silent (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.960C>A p.T320= | Silent (SNP) | VAF 19/148 reads (13%) | called by muse, mutect2, varscan2
- CYP2W1 | c.1035C>A p.P345= | Silent (SNP) | VAF 80/192 reads (42%) | catalogued as COSV58270680; called by muse, mutect2, varscan2
- CYRIA | c.573A>T p.A191= | Silent (SNP) | VAF 26/313 reads (8%) | called by muse, mutect2
- DAB1 | c.168G>A p.R56= | Silent (SNP) | VAF 28/416 reads (7%) | called by muse, mutect2
- ENPP1 | c.1659T>A p.P553= | Silent (SNP) | VAF 35/425 reads (8%) | called by muse, mutect2
- EPHA8 | c.291C>G p.V97= | Silent (SNP) | VAF 33/319 reads (10%) | called by muse, mutect2, varscan2
- EWSR1 | c.999C>T p.F333= | Silent (SNP) | VAF 14/228 reads (6%) | called by muse, mutect2
- FAM133A | c.63C>A p.G21= | Silent (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- FAM47B | c.744C>G p.R248= | Silent (SNP) | VAF 71/222 reads (32%) | catalogued as rs369604412, COSV61454690; called by muse, mutect2, varscan2
- FAT2 | c.11709G>A p.S3903= | Silent (SNP) | VAF 49/708 reads (7%) | catalogued as rs758597109; called by muse, mutect2
- FAT2 | c.3591C>A p.A1197= | Silent (SNP) | VAF 74/283 reads (26%) | called by muse, mutect2, varscan2
- FGF18 | c.429G>T p.S143= | Silent (SNP) | VAF 94/416 reads (23%) | catalogued as COSV51127847; called by muse, varscan2
- FLNC | c.4164G>A p.E1388= | Silent (SNP) | VAF 44/247 reads (18%) | catalogued as rs1273630397; called by muse, mutect2, varscan2
- FSIP2 | c.17127C>T p.P5709= | Silent (SNP) | VAF 27/260 reads (10%) | called by muse, mutect2
- GIMAP1 | c.637C>T p.L213= | Silent (SNP) | VAF 37/206 reads (18%) | called by muse, mutect2, varscan2
- GPR15 | c.204C>A p.I68= | Silent (SNP) | VAF 56/316 reads (18%) | catalogued as rs755310153, COSV52520348, COSV52520749, COSV52520817; called by muse, mutect2, varscan2
- GRIK2 | c.2496G>A p.V832= | Silent (SNP) | VAF 26/318 reads (8%) | called by muse, mutect2
- HCRTR2 | c.618C>A p.L206= | Silent (SNP) | VAF 105/426 reads (25%) | called by muse, mutect2, varscan2
- HIPK4 | c.1431C>T p.F477= | Silent (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- HS3ST2 | c.15C>A p.V5= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as rs536147010; called by muse, mutect2, varscan2
- IGKV6D-41 | c.333C>G p.G111= | Silent (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2
- KIAA0930 | c.1155G>T p.P385= (on ENST00000336156 / NM_001009880.2; = p.P390= on NM_015264.2) | Silent (SNP) | VAF 33/221 reads (15%) | called by muse, mutect2, varscan2
- KMT2B | c.660G>T p.R220= | Silent (SNP) | VAF 26/171 reads (15%) | called by muse, mutect2, varscan2
- MAS1 | c.897G>C p.L299= | Silent (SNP) | VAF 15/264 reads (6%) | called by muse, mutect2
- MATN1 | c.1431G>A p.L477= | Silent (SNP) | VAF 16/268 reads (6%) | called by muse, mutect2
- MMS22L | c.3396G>T p.L1132= | Silent (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- NRG3 | c.561T>C p.T187= | Silent (SNP) | VAF 37/231 reads (16%) | called by muse, mutect2, varscan2
- NRXN1 | c.3930C>A p.A1310= | Silent (SNP) | VAF 28/248 reads (11%) | called by muse, mutect2, varscan2
- OPCML | c.612G>C p.A204= | Silent (SNP) | VAF 33/273 reads (12%) | called by muse, mutect2, varscan2
- OR2H1 | c.84T>G p.V28= | Silent (SNP) | VAF 18/472 reads (4%) | called by muse, mutect2
- OR2M5 | c.213C>A p.L71= | Silent (SNP) | VAF 55/228 reads (24%) | called by muse, mutect2, varscan2
- OR2M5 | c.405C>A p.L135= | Silent (SNP) | VAF 96/363 reads (26%) | called by muse, mutect2, varscan2
- OR51T1 | c.429C>T p.V143= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as COSV59024109; called by muse, mutect2, varscan2
- OTOG | c.8448C>A p.A2816= | Silent (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- OTX2 | c.528C>A p.P176= (on ENST00000408990 / NM_172337.3; = p.P184= on NM_021728.4) | Silent (SNP) | VAF 28/326 reads (9%) | catalogued as rs766762080; called by muse, mutect2
- PARS2 | c.855A>G p.L285= | Silent (SNP) | VAF 57/379 reads (15%) | called by muse, mutect2, varscan2
- PCDH17 | c.1428C>A p.L476= | Silent (SNP) | VAF 42/675 reads (6%) | called by muse, mutect2
- PEG3 | c.471C>T p.V157= | Silent (SNP) | VAF 22/505 reads (4%) | called by muse, mutect2
- PITPNM3 | c.1710G>C p.L570= | Silent (SNP) | VAF 18/515 reads (3%) | called by muse, mutect2
- PITPNM3 | c.1708C>T p.L570= | Silent (SNP) | VAF 17/504 reads (3%) | catalogued as rs1309432598; called by muse, mutect2
- PLA2G4D | c.1704G>C p.S568= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99299796; called by muse, mutect2, varscan2
- PLXNB3 | c.2721G>A p.R907= | Silent (SNP) | VAF 14/147 reads (10%) | catalogued as COSV100737889; called by muse, mutect2
- PPIP5K2 | c.3402T>C p.L1134= (on ENST00000358359 / NM_001276277.3; = p.L1113= on NM_015216.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 40/169 reads (24%) | called by muse, mutect2, varscan2
- PSG5 | c.57G>T p.L19= | Silent (SNP) | VAF 42/464 reads (9%) | called by muse, mutect2
- PSG9 | c.9C>G p.P3= | Silent (SNP) | VAF 41/305 reads (13%) | catalogued as COSV52483555; called by muse, mutect2, varscan2
- R3HDM2 | c.1902G>T p.V634= | Silent (SNP) | VAF 52/1287 reads (4%) | called by muse, mutect2
- RAB6C | c.366G>C p.T122= | Silent (SNP) | VAF 58/723 reads (8%) | called by muse, mutect2
- RALGAPA2 | c.4746T>C p.S1582= | Silent (SNP) | VAF 60/540 reads (11%) | called by muse, mutect2, varscan2
- RASA2 | c.1314C>T p.I438= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs751326898; ClinVar: likely benign; called by muse, mutect2, varscan2
- RERGL | c.373C>A p.R125= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV57461607; called by muse, varscan2
- RNF19A | c.1596G>A p.L532= | Silent (SNP) | VAF 27/942 reads (3%) | called by muse, mutect2
- SLC16A12 | c.1251T>G p.L417= | Silent (SNP) | VAF 32/370 reads (9%) | called by muse, mutect2
- SMARCAL1 | c.1932G>C p.R644= | Silent (SNP) | VAF 26/502 reads (5%) | called by muse, mutect2
- SORCS3 | c.525G>T p.G175= | Silent (SNP) | VAF 22/152 reads (14%) | catalogued as rs776138077; called by muse, mutect2, varscan2
- SPOPL | c.915C>G p.T305= | Silent (SNP) | VAF 25/416 reads (6%) | called by muse, mutect2
- SPTA1 | c.4245G>A p.E1415= | Silent (SNP) | VAF 26/383 reads (7%) | catalogued as COSV63752634, COSV63753401; called by muse, mutect2
- SRRM2 | c.3018G>A p.G1006= | Silent (SNP) | VAF 57/297 reads (19%) | catalogued as rs1220181092; called by muse, mutect2, varscan2
- TGM6 | c.594C>A p.P198= | Silent (SNP) | VAF 149/806 reads (18%) | called by muse, mutect2, varscan2
- TPP2 | c.2961C>T p.I987= | Silent (SNP) | VAF 22/266 reads (8%) | called by muse, mutect2
- TPST1 | c.849G>A p.V283= | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- TRIM64B | c.1284C>A p.I428= | Silent (SNP) | VAF 28/334 reads (8%) | called by muse, mutect2, varscan2
- TSHZ2 | c.624G>T p.V208= | Silent (SNP) | VAF 51/265 reads (19%) | called by muse, mutect2, varscan2
- TSHZ2 | c.2304C>A p.T768= | Silent (SNP) | VAF 30/142 reads (21%) | called by muse, mutect2, varscan2
- XKR7 | c.1644C>A p.I548= | Silent (SNP) | VAF 27/330 reads (8%) | catalogued as COSV73813384; called by muse, mutect2
- YARS2 | c.129G>A p.K43= | Silent (SNP) | VAF 52/246 reads (21%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.900G>A p.V300= | Silent (SNP) | VAF 20/222 reads (9%) | called by muse, mutect2
- ZIM2 | c.528G>T p.V176= | Silent (SNP) | VAF 9/163 reads (6%) | called by muse, mutect2
- AK2 | c.-8C>T | 5'UTR (SNP) | VAF 27/466 reads (6%) | catalogued as rs930991730; called by muse, mutect2
- AP000679.1 | n.1066G>A | RNA (SNP) | VAF 57/541 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915988 G>T | 5'Flank (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- CCNC | c.346+52C>G | Intron (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- COL13A1 | c.1650+642G>C | Intron (SNP) | VAF 42/302 reads (14%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*110A>G | 3'UTR (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- DCC | c.4255-174C>T | Intron (SNP) | VAF 33/237 reads (14%) | called by muse, mutect2, varscan2
- DIAPH2 | c.3241+39974G>T | Intron (SNP) | VAF 30/140 reads (21%) | called by mutect2, varscan2
- FOLH1B | n.1024G>A | RNA (SNP) | VAF 27/235 reads (11%) | called by muse, mutect2, varscan2
- GIPR | c.281-44C>T | Intron (SNP) | VAF 13/311 reads (4%) | called by muse, mutect2
- GP2 | chr16:20327559 T>A | 5'Flank (SNP) | VAF 24/330 reads (7%) | called by muse, mutect2
- HADH | c.709+47G>T | Intron (SNP) | VAF 30/424 reads (7%) | called by muse, mutect2
- KRT8P11 | n.1327G>A | RNA (SNP) | VAF 21/209 reads (10%) | called by muse, mutect2, varscan2
- LINC02054 | n.2595-11603T>A | Intron (SNP) | VAF 50/335 reads (15%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85689G>T | Intron (SNP) | VAF 87/826 reads (11%) | catalogued as rs755203559; called by muse, varscan2
- MLANA | chr9:5913993 G>C | 3'Flank (SNP) | VAF 29/239 reads (12%) | catalogued as rs751857964; called by muse, mutect2, varscan2
- MUC6 | c.3808+37C>T | Intron (SNP) | VAF 57/493 reads (12%) | called by muse, mutect2, varscan2
- MXD3 | c.*336C>T | 3'UTR (SNP) | VAF 12/266 reads (5%) | catalogued as rs1251317767; called by muse, mutect2
- NOC2LP2 | n.1589A>T | RNA (SNP) | VAF 26/523 reads (5%) | called by muse, mutect2
- NOC2LP2 | n.969C>T | RNA (SNP) | VAF 52/410 reads (13%) | called by muse, varscan2
- NOTCH2 | c.*5G>C | 3'UTR (SNP) | VAF 35/727 reads (5%) | called by muse, mutect2
- OR7E5P | n.358G>T | RNA (SNP) | VAF 40/478 reads (8%) | called by muse, mutect2
- PPIB | c.343+68G>T | Intron (SNP) | VAF 25/402 reads (6%) | catalogued as rs1203394876; called by muse, mutect2
- REG1A | c.183+46G>T | Intron (SNP) | VAF 28/312 reads (9%) | called by muse, mutect2
- RFPL4AP1 | n.536G>T | RNA (SNP) | VAF 101/1007 reads (10%) | catalogued as rs1411167166; called by muse, mutect2, varscan2
- SAV1 | c.*997C>T | 3'UTR (SNP) | VAF 11/299 reads (4%) | called by muse, mutect2
- SLC12A5 | c.1406-26G>T | Intron (SNP) | VAF 17/248 reads (7%) | called by muse, mutect2
- SLC29A3 | c.*691G>T | 3'UTR (SNP) | VAF 59/464 reads (13%) | called by muse, mutect2, varscan2
- SLC9B1P1 | n.1059G>A | RNA (SNP) | VAF 25/243 reads (10%) | called by muse, mutect2
- SORL1 | c.3461-349G>C | Intron (SNP) | VAF 76/523 reads (15%) | called by muse, mutect2, varscan2
- TBC1D1 | c.1910+2128A>C | Intron (SNP) | VAF 13/266 reads (5%) | called by muse, mutect2
- TRA2B | c.-31G>T | 5'UTR (SNP) | VAF 27/139 reads (19%) | catalogued as rs762291620; called by muse, mutect2, varscan2
- TRAV19 | c.-16G>C | 5'UTR (SNP) | VAF 54/253 reads (21%) | called by muse, mutect2, varscan2
- TRIML2 | c.621+774C>A | Intron (SNP) | VAF 18/192 reads (9%) | called by muse, mutect2
- TRPA1 | c.-42_-41del | 5'UTR (DEL) | VAF 38/270 reads (14%) | called by pindel, varscan2
- UACA | c.79-3514A>T | Intron (SNP) | VAF 32/322 reads (10%) | called by muse, varscan2
